Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A4U9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A4U9-06A (Metastatic).

[page 1 of 3]
SPECIMEN(S):

- A. RIGHT GROIN SUPERFICIAL DISSECTION
- B. RIGHT OBTURATOR LYMPH NODES
- C. RIGHT GROIN DEEP LYMPH NODE
- D. RIGHT GROIN DEEP LYMPH NODES ADDITIONAL
- E. HIGHEST NODE RIGHT GROIN

CLINICAL HISTORY:

None Given

ICD-0-3

Melanoma, NOS 8720/3
Site: lymph node, groin
C77.4

PRE-OPERATIVE DIAGNOSIS:

In transit melanoma right groin and leg

hw
10/10/12

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSC-right groin deep lymph node: Negative for melanoma.

FSE-highest node right groin: Negative for melanoma.

Diagnosis called

DIAGNOSIS:

A. LYMPH NODE, RIGHT GROIN SUPERFICIAL, EXCISION:

-METASTATIC MALIGNANT MELANOMA (6/13), LARGEST FOCUS MEASURING 2.2 CM

B. LYMPH NODES, RIGHT OBTURATOR, EXCISION:

-LYMPH NODES NEGATIVE FOR MELANOMA (0/4)

[page 2 of 3]
C. LYMPH NODE, RIGHT GROIN DEEP, EXCISION:

-LYMPH NODE NEGATIVE FOR MELANOMA (0/1)

D. LYMPH NODE, RIGHT GROIN DEEP ADDITIONAL, EXCISION:

-METASTATIC MALIGNANT MELANOMA (2/8), MICROSCOPIC FOCI

E. LYMPH NODE, HIGHEST RIGHT GROIN, EXCISION:

-LYMPH NODE NEGATIVE FOR MELANOMA (0/1)

GROSS DESCRIPTION:

A. RIGHT GROIN SUPERFICIAL DISSECTION

Received fresh labeled with the patient's identification and "right groin superficial dissection" is a 30 x 11.5 x 6 cm piece of yellow-tan fat containing a 7.2 x 6.5 x 6.5 cm hemorrhagic necrotic gray-tan lymph node and additional lymph nodes ranging from 0.6 x 0.5 x 0.3 cm to 3.2 x 1.5 x 0.8 cm. The larger lymph nodes are bisected and range from pink-tan to red-gray cut surfaces. There is a 4.7 x 0.4 cm blood vessel with a 0.2 cm lumen. Tissue is procured; representatively submitted:

A1: 1 bisected lymph node and cross sections from large blood vessel

A2: 5 lymph nodes

A3: 2 bisected lymph nodes (one inked black)

A4-A6: 1 sectioned lymph node in each cassette

A7-A10: sections from largest lymph node

B. RIGHT OBTURATOR LYMPH NODES

Received in formalin labeled with the patient's identification and "right obturator lymph node" are pieces of yellow-tan soft tissue in aggregate, 5.7 x 1.1 x 1.5 cm containing 4 lymph nodes ranging from 0.6 x 0.6 x 0.6 cm to 5.2 x 2.1 x 1.3 cm; lymph nodes are submitted entirely:

B1: 3 lymph nodes

B2-B4: 1 lymph node

C. RIGHT GROIN DEEP LYMPH NODE

[page 3 of 3]
Received fresh labeled with the patient's identification and "right groin deep lymph node" is a 2.2 x 1.2 x 0.9 cm lymph node; sectioned and submitted entirely for frozen section diagnosis in cassette FSC.

D. RIGHT GROIN DEEP LYMPH NODE

Received in formalin labeled with the patient's identification and "right groin deep lymph node" are pieces of yellow-tan soft tissue in aggregate, 10 x 5 x 1.3 cm containing a piece of mesh, 5 x 2.5 x 0.5 cm and lymph nodes ranging from 1 x 0.5 x 0.5 cm to 2.3 x 1.5 x 0.7 cm; lymph nodes are submitted entirely:

D1: 2 lymph nodes

D2: 2 lymph nodes (1 inked green)

D3-D6: 1 bisected lymph node in each cassette

E. HIGHEST NODE RIGHT GROIN

Received fresh labeled with the patient's identification and "highest node right groin" is a 1.5 x 1.0 x 0.6 cm lymph node; sectioned and submitted entirely for frozen section diagnosis in cassette FSE.

ADDENDUM: Tumor was sent to Laboratories. The results are as follows:

- FOR THE C-KIT GENE, NO ACTIVATING MUTATIONS WERE DETECTED IN EXONS 9, 11, 13, AND 17.

- FOR FURTHER DETAILS PLEASE SEE THE OUTSIDE REPORT

Source: NCI Genomic Data Commons file 2a55bca9-f6b7-4650-9ff6-1d7d85226827 (TCGA-GN-A4U9.13096A76-D4DF-412C-B713-B2BB538B23DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).